Somatic mutation profile of tumor specimen TCGA-AN-A0AT-01A (aliquot TCGA-AN-A0AT-01A-11D-A045-09) from TCGA case TCGA-AN-A0AT, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.4 years (22,798 days).
Specimen TCGA-AN-A0AT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f44e604b-b64f-4ca9-85c7-b3d21945b06f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0AT-10A (Blood Derived Normal), aliquot TCGA-AN-A0AT-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ad44d2e-f028-4ea3-a40b-ad7479dc0cce

The open-access MAF lists 126 somatic variants for this specimen: 101 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 21, Frame Shift Del 5, Nonsense Mutation 3, Intron 2, Splice Site 1, RNA 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PROC | c.1216A>G p.M406V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553425459, COSV52166986; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.2845C>A p.P949T (on ENST00000372530 / NM_001198934.2; = p.P921T on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV55090381; called by muse, mutect2, varscan2
- ADAMTS14 | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64603956; called by muse, mutect2, varscan2
- ADCY9 | c.1711A>T p.I571L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV53578064; called by muse, mutect2, varscan2
- ALMS1 | c.9679C>T p.H3227Y | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV52514617; called by muse, mutect2, varscan2
- ANKRD30A | c.2862A>T p.K954N (on ENST00000611781; = p.K898N on NM_052997.2) | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV64614994; called by muse, mutect2, varscan2
- ARHGAP24 | c.1666T>C p.S556P (on ENST00000395184 / NM_001025616.3; = p.S463P on NM_031305.3) | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51991068; called by muse, mutect2
- ARID3C | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs1442419695, COSV52406979; called by muse, mutect2, varscan2
- ASB17 | c.808A>T p.T270S | Missense Mutation (SNP) | VAF 37/507 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99407888; called by muse, mutect2
- B3GALT1 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV59909212; called by muse, mutect2, varscan2
- BCL2L11 | c.250A>G p.R84G | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV58031060; called by muse, mutect2, varscan2
- BRCA2 | c.7948G>C p.E2650Q | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66452400; called by muse, mutect2, varscan2
- C15orf39 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as COSV62297294; called by muse, mutect2, varscan2
- CACNA1B | c.4903C>T p.H1635Y | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV53135867; called by muse, mutect2, varscan2
- CAD | c.1773C>A p.D591E | Missense Mutation (SNP) | VAF 120/380 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV53028989; called by muse, mutect2, varscan2
- CCDC170 | c.1177A>G p.R393G | Missense Mutation (SNP) | VAF 80/319 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53343076; called by muse, mutect2, varscan2
- CEACAM21 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781900469, COSV51815048; called by muse, mutect2, varscan2
- CHRM2 | c.562T>A p.F188I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57777705; called by muse, mutect2, varscan2
- CHRNA2 | c.1131G>A p.W377* | Nonsense Mutation (SNP) | VAF 6/67 reads (9%) | catalogued as COSV99532101; called by muse, mutect2
- CNNM4 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100998649, COSV65660409; called by muse, mutect2
- CNTNAP5 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs890816163, COSV70496411, COSV70507161; called by muse, mutect2, varscan2
- CTCF | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 60/170 reads (35%) | catalogued as COSV50482124; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1364T>A p.I455N | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV54745554; called by muse, mutect2, varscan2
- CUL5 | c.1960G>A p.V654I | Missense Mutation (SNP) | VAF 126/248 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV67609488; called by muse, mutect2, varscan2
- DGKI | c.1615G>T p.V539F | Missense Mutation (SNP) | VAF 137/224 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55961242, COSV55962351; called by muse, mutect2, varscan2
- DNAH6 | c.1803G>T p.K601N | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV52870411; called by muse, mutect2, varscan2
- DNMBP | c.3178G>A p.V1060M | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.805); catalogued as COSV60628919; called by muse, mutect2, varscan2
- DRAM1 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 278/814 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as COSV51599008; called by muse, mutect2, varscan2
- DST | c.19537T>A p.S6513T (on ENST00000361203 / NM_001374722.1; = p.S4210T on NM_015548.5) | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV55025618; called by muse, mutect2, varscan2
- ERBB4 | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 105/292 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as rs1185985735, COSV61502900; called by muse, mutect2, varscan2
- ERLEC1 | c.1031G>T p.C344F | Missense Mutation (SNP) | VAF 73/331 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51752642; called by muse, mutect2, varscan2
- EXOC1 | c.1156C>T p.L386F | Missense Mutation (SNP) | VAF 118/352 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as rs1332633276, COSV62121069; called by muse, mutect2, varscan2
- FASTKD1 | c.1285C>G p.P429A | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV71624472; called by muse, mutect2, varscan2
- FMN2 | c.4600C>A p.L1534I | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60439595; called by muse, mutect2, varscan2
- FNTB | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV55762635; called by muse, mutect2, varscan2
- FZD7 | c.268G>C p.V90L | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV53810592; called by muse, mutect2, varscan2
- GATM | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 94/202 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV67540733; called by muse, mutect2, varscan2
- GNAQ | c.492G>T p.L164F | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV54118755; called by muse, mutect2, varscan2
- GON4L | c.1789-2A>C p.X597_splice | Splice Site (SNP) | VAF 129/440 reads (29%) | catalogued as COSV55197638; called by muse, mutect2, varscan2
- HIVEP2 | c.4601G>T p.R1534M | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.174); catalogued as COSV50024446; called by muse, mutect2, varscan2
- HYDIN | c.2164C>G p.L722V | Missense Mutation (SNP) | VAF 93/300 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV55491295; called by muse, mutect2, varscan2
- IGDCC3 | c.269T>G p.L90W | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV60078588; called by muse, mutect2, varscan2
- IL6R | c.1374C>G p.D458E | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV59817629; called by muse, mutect2, varscan2
- INSRR | c.2708_2711del p.D903Vfs*53 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | catalogued as rs1444799871; called by pindel, varscan2
- IQSEC2 | c.3082G>C p.V1028L (on ENST00000642864 / NM_001111125.3; = p.V823L on NM_015075.2) | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.102); catalogued as COSV64726721; called by muse, mutect2, varscan2
- KLK8 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51593245; called by muse, mutect2, varscan2
- KREMEN1 | c.473T>G p.F158C (on ENST00000407188; = p.F160C on NM_032045.5) | Missense Mutation (SNP) | VAF 91/265 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs775424604, COSV59913664; called by muse, mutect2, varscan2
- LRP8 | c.1825T>C p.S609P | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60099802; called by muse, mutect2, varscan2
- LRRFIP1 | c.892A>G p.R298G (on ENST00000392000 / NM_001137552.2; = p.R274G on NM_004735.4) | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1559824626, COSV55253770; called by muse, mutect2, varscan2
- MACO1 | c.1256G>T p.R419L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV65476530, COSV65477230; called by muse, mutect2, varscan2
- MIS18BP1 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as COSV60371875; called by muse, mutect2, varscan2
- MMP24 | c.785A>C p.E262A | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55771486; called by muse, mutect2, varscan2
- MYO18B | c.6731C>G p.P2244R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59140662; called by muse, mutect2, varscan2
- NKD1 | c.668G>T p.W223L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV51692496; called by muse, mutect2, varscan2
- NR2E1 | c.811G>C p.V271L | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV64561655, COSV64562372; called by muse, mutect2, varscan2
- NUMA1 | c.1665G>C p.Q555H | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61187937; called by muse, mutect2, varscan2
- OGDHL | c.2452T>A p.C818S | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV65103507; called by muse, mutect2, varscan2
- OPRPN | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 216/666 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.094); catalogued as COSV68193238; called by muse, varscan2
- OR4K2 | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 126/383 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as COSV53849436, COSV53850493; called by muse, mutect2, varscan2
- PCCB | c.1096T>G p.L366V | Missense Mutation (SNP) | VAF 190/388 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52446401; called by muse, mutect2, varscan2
- PDE4DIP | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV57708921; called by muse, mutect2, varscan2
- POU2F2 | c.117C>G p.D39E | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.956); catalogued as COSV60764912; called by muse, varscan2
- PRDM1 | c.1047C>G p.S349R | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.409); catalogued as COSV100958915, COSV64845852; called by muse, mutect2, varscan2
- PRKG2 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV52327600; called by muse, mutect2, varscan2
- QRICH2 | c.2201G>C p.G734A | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV53155084; called by muse, mutect2, varscan2
- RLF | c.388G>C p.V130L | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV65652371; called by muse, mutect2, varscan2
- SBF2 | c.4024G>C p.E1342Q | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV56293784, COSV56300731; called by muse, mutect2
- SCN7A | c.4948G>T p.D1650Y | Missense Mutation (SNP) | VAF 94/311 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.819); catalogued as COSV69270401, COSV69272984; called by muse, mutect2, varscan2
- SEMA4A | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV61773264; called by muse, mutect2, varscan2
- SFXN5 | c.209A>C p.Y70S | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55588329; called by muse, mutect2, varscan2
- SIGLEC1 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.022); catalogued as rs745472020, COSV52460722; called by muse, mutect2, varscan2
- SLC17A8 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 238/857 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60125120; called by muse, mutect2, varscan2
- SMOC2 | c.199C>A p.Q67K | Missense Mutation (SNP) | VAF 150/286 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV62440566; called by muse, mutect2, varscan2
- SOGA1 | c.1619T>G p.L540R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52923876; called by muse, mutect2, varscan2
- SPATA16 | c.1172A>C p.K391T | Missense Mutation (SNP) | VAF 11/330 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100651094; called by muse, mutect2
- STAB2 | c.3799A>T p.I1267F | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66342332; called by muse, mutect2, varscan2
- SYNE1 | c.677A>C p.D226A (on ENST00000367255 / NM_182961.4; = p.D233A on NM_033071.3) | Missense Mutation (SNP) | VAF 84/367 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55032083; called by muse, mutect2, varscan2
- TEX13A | c.419A>C p.Q140P | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61167474; called by muse, mutect2, varscan2
- TFAP4 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV52597118; called by muse, mutect2, varscan2
- TGFB1 | c.590del p.S197Ffs*12 | Frame Shift Del (DEL) | VAF 36/65 reads (55%) | catalogued as COSV55725734; called by mutect2, varscan2
- TIMM44 | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 76/116 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.106); catalogued as COSV54492917; called by muse, mutect2, varscan2
- TLE4 | c.958G>T p.V320F | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.668); catalogued as COSV54629888, COSV54635624; called by muse, mutect2, varscan2
- TRANK1 | c.5346G>T p.E1782D | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as rs763539292, COSV57156016, COSV57163297; called by muse, mutect2
- TRMT12 | c.1163C>G p.T388S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV60777395; called by muse, mutect2, varscan2
- TRMT2B | c.1175C>A p.T392N | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.156); catalogued as rs750928011, COSV58620246; called by muse, varscan2
- TTC21A | c.1718T>C p.L573P | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57187125; called by muse, mutect2, varscan2
- TTN | c.10987A>G p.T3663A (on ENST00000591111; = p.T3617A on NM_003319.4) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV60180020; called by muse, mutect2, varscan2
- UPF3B | c.1082G>A p.R361Q (on ENST00000276201 / NM_080632.3; = p.R348Q on NM_023010.3) | Missense Mutation (SNP) | VAF 79/385 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs773491980, COSV52230697; called by muse, mutect2, varscan2
- USP45 | c.1439C>G p.S480* | Nonsense Mutation (SNP) | VAF 6/108 reads (6%) | catalogued as COSV100569585; called by muse, mutect2
- VCAN | c.1708A>T p.T570S | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as rs545968358, COSV54110227; called by muse, mutect2, varscan2
- VWA3A | c.1451G>C p.R484T | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV100241048, COSV55393057; called by muse, mutect2, varscan2
- WFDC3 | c.167G>C p.C56S | Missense Mutation (SNP) | VAF 106/306 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV54785680; called by muse, mutect2
- ZFYVE1 | c.968_975del p.H323Pfs*5 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as COSV59611793; called by mutect2, pindel, varscan2
- ZIM3 | c.431A>T p.N144I | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV54144370; called by muse, mutect2, varscan2
- ZNF418 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs376873884; called by muse, mutect2, varscan2
- ZNF613 | c.1130G>T p.C377F (on ENST00000293471 / NM_001031721.4; = p.C341F on NM_024840.4) | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53272814; called by muse, mutect2, varscan2
- CREBBP | c.2390dup p.N797Kfs*35 | Frame Shift Ins (INS) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.1986G>C p.E662D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- H4C5 | c.79A>T p.I27F | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- TNFRSF10D | c.444_448del p.D148Efs*4 | Frame Shift Del (DEL) | VAF 50/139 reads (36%) | called by mutect2, pindel, varscan2
- TTLL2 | c.433_448del p.N145Pfs*14 | Frame Shift Del (DEL) | VAF 68/466 reads (15%) | called by mutect2, pindel, varscan2
- ACAT2 | c.432C>T p.D144= | Silent (SNP) | VAF 117/362 reads (32%) | catalogued as COSV65454385; called by muse, mutect2, varscan2
- BBS2 | c.102C>T p.A34= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV55327407; called by muse, mutect2, varscan2
- DOCK11 | c.5535A>G p.K1845= | Silent (SNP) | VAF 80/210 reads (38%) | catalogued as COSV52243261; called by muse, mutect2, varscan2
- DPH2 | c.175T>C p.L59= | Silent (SNP) | VAF 41/281 reads (15%) | catalogued as rs377624927; called by muse, mutect2, varscan2
- FADS2 | c.588T>A p.L196= | Silent (SNP) | VAF 133/415 reads (32%) | catalogued as COSV53900359; called by muse, mutect2, varscan2
- FNDC11 | c.720T>C p.Y240= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV64443112; called by muse, mutect2, varscan2
- FNTB | c.732G>T p.G244= | Silent (SNP) | VAF 36/236 reads (15%) | catalogued as COSV55762645; called by muse, mutect2, varscan2
- ITGAD | c.1224C>A p.T408= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs577953379, COSV66758809; called by muse, varscan2
- MAP3K21 | c.2256G>A p.L752= | Silent (SNP) | VAF 77/175 reads (44%) | catalogued as rs1381941706, COSV64042139; called by muse, mutect2, varscan2
- MRC1 | c.447C>T p.C149= | Silent (SNP) | VAF 47/322 reads (15%) | called by muse, mutect2, varscan2
- NAALADL1 | c.177G>A p.E59= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV60523005; called by muse, mutect2, varscan2
- NFIA | c.1182G>A p.E394= | Silent (SNP) | VAF 138/312 reads (44%) | catalogued as COSV63609271; called by muse, mutect2, varscan2
- NPTXR | c.1359G>C p.L453= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV60728866; called by muse, mutect2, varscan2
- PAQR6 | c.393C>T p.A131= (on ENST00000292291 / NM_001272108.2; = p.A25= on NM_024897.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs1455171492, COSV52745879; called by muse, mutect2
- PKHD1 | c.4131T>C p.N1377= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV61885480; called by muse, mutect2, varscan2
- PUM1 | c.1881G>A p.Q627= | Silent (SNP) | VAF 121/442 reads (27%) | catalogued as COSV57083770, COSV57088229; called by muse, mutect2, varscan2
- SLC25A14 | c.396C>T p.F132= | Silent (SNP) | VAF 37/214 reads (17%) | catalogued as rs747244165, COSV54419048; called by muse, mutect2, varscan2
- SLC44A2 | c.741C>T p.L247= | Silent (SNP) | VAF 503/679 reads (74%) | catalogued as COSV59837767; called by muse, mutect2, varscan2
- TMOD1 | c.108G>A p.E36= | Silent (SNP) | VAF 14/413 reads (3%) | catalogued as COSV52249847; called by muse, mutect2
- VPS52 | c.1557T>C p.A519= | Silent (SNP) | VAF 94/193 reads (49%) | catalogued as rs551574533, COSV71403548; called by muse, mutect2, varscan2
- ZNF597 | c.174G>A p.K58= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as COSV57084892; called by muse, mutect2, varscan2
- CALCA | chr11:14967761 G>C | 3'Flank (SNP) | VAF 30/126 reads (24%) | catalogued as COSV59028182; called by muse, mutect2, varscan2
- NBPF11 | c.-549+2445G>T | Intron (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- OR2U1P | n.52A>G | RNA (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23322C>A | Intron (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100530111; called by muse, mutect2
